Somatic mutation profile of tumor specimen C3L-01882-01 (aliquot CPT0092730009) from CPTAC case C3L-01882, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 48.8 years (17,820 days).
Specimen C3L-01882-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ff76c6b-9f81-430c-b4b1-53c397cfa229.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01882-31 (Blood Derived Normal), aliquot CPT0093820002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b4c86d6-934e-44cc-bc63-f7e11092a59c

The open-access MAF lists 59 somatic variants for this specimen: 35 protein-altering or splice-affecting, 7 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Intron 9, Silent 7, Frame Shift Del 5, RNA 3, 3'UTR 3, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RIT1 | c.268A>G p.M90V | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1557960039, CM167019, COSV64170951; ClinVar: pathogenic; called by muse, mutect2
- APOH | c.790T>C p.C264R | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1409996632; called by muse, mutect2, varscan2
- ARHGEF35 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 36/242 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV65312384; called by muse, mutect2, varscan2
- COLQ | c.844A>G p.R282G | Missense Mutation (SNP) | VAF 49/379 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs121908922, CM980417; called by muse, mutect2, varscan2
- GIMAP1 | c.325G>C p.A109P | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV56188944; called by muse, mutect2
- KIF22 | c.1796G>A p.G599D | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1395764185, COSV99360914; called by muse, mutect2, varscan2
- LENG8 | c.2144del p.F715Sfs*30 | Frame Shift Del (DEL) | VAF 24/285 reads (8%) | catalogued as COSV58730905; called by mutect2, pindel
- MS4A3 | c.575T>A p.I192K | Missense Mutation (SNP) | VAF 41/283 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs770173506; called by muse, mutect2, varscan2
- PEPD | c.842A>G p.Y281C | Missense Mutation (SNP) | VAF 49/627 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs766027294; called by muse, mutect2
- TAF4 | c.2468C>A p.P823H | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV53339647; called by muse, mutect2, varscan2
- TLK2 | c.545G>A p.S182N | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV58298720; called by muse, varscan2
- ANKRD66 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 33/274 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- AZIN2 | c.1055A>T p.Y352F | Missense Mutation (SNP) | VAF 38/215 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- C5orf52 | c.369A>C p.E123D | Missense Mutation (SNP) | VAF 30/265 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAH2 | c.2974G>T p.A992S | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.01); called by muse, mutect2
- FAM168A | c.556G>T p.A186S (on ENST00000064778 / NM_001286050.2; = p.A177S on NM_015159.3) | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- FAT4 | c.6758del p.N2253Mfs*14 | Frame Shift Del (DEL) | VAF 24/240 reads (10%) | called by mutect2, pindel
- HARS2 | c.1352C>A p.T451N | Missense Mutation (SNP) | VAF 81/607 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HIVEP1 | c.1183C>G p.L395V | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2
- LAMA2 | c.5692G>A p.A1898T | Missense Mutation (SNP) | VAF 40/326 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- LRRC66 | c.139T>G p.S47A | Missense Mutation (SNP) | VAF 40/355 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- OAZ3 | c.199C>T p.L67F | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OGT | c.2708_2717delinsTTTTTTTTTT p.S903_A906delinsFFFF | Missense Mutation (ONP) | VAF 4/46 reads (9%) | called by mutect2*, pindel
- PCSK7 | c.802A>G p.S268G | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2
- PDLIM2 | c.55G>A p.G19R (on ENST00000397760; = p.G269R on NM_021630.6) | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- PSG6 | c.1157A>C p.N386T | Missense Mutation (SNP) | VAF 53/375 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SPHKAP | c.3061G>T p.V1021F | Missense Mutation (SNP) | VAF 16/217 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TAOK1 | c.2574T>A p.N858K | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.97); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- TCHHL1 | c.1160T>G p.M387R | Missense Mutation (SNP) | VAF 45/341 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- THBS2 | c.1372_1373del p.I458Hfs*67 | Frame Shift Del (DEL) | VAF 38/278 reads (14%) | called by pindel, varscan2
- URGCP | c.2691del p.A898Pfs*5 (on ENST00000453200 / NM_001077663.3; = p.A889Pfs*5 on NM_017920.4) | Frame Shift Del (DEL) | VAF 46/340 reads (14%) | called by mutect2, pindel, varscan2
- VLDLR | c.49T>C p.W17R | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- ZBBX | c.1699_1700del p.E567Ifs*18 | Frame Shift Del (DEL) | VAF 11/82 reads (13%) | called by mutect2, pindel, varscan2
- ZNF142 | c.2194G>T p.A732S (on ENST00000411696 / NM_001379660.1; = p.A532S on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/302 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- ZNF248 | c.1472C>G p.P491R | Missense Mutation (SNP) | VAF 36/243 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- A2ML1 | c.2391T>G p.P797= | Silent (SNP) | VAF 42/399 reads (11%) | called by muse, mutect2, varscan2
- C16orf96 | c.3183T>C p.S1061= | Silent (SNP) | VAF 24/231 reads (10%) | called by muse, mutect2, varscan2
- CASKIN1 | c.3384C>T p.I1128= | Silent (SNP) | VAF 26/212 reads (12%) | called by muse, mutect2, varscan2
- FCHO1 | c.1155C>A p.G385= | Silent (SNP) | VAF 23/190 reads (12%) | catalogued as rs1196358868, COSV53183542; called by muse, mutect2, varscan2
- KCTD9 | c.120C>A p.T40= | Silent (SNP) | VAF 19/157 reads (12%) | called by muse, mutect2, varscan2
- MTX3 | c.294C>T p.L98= | Silent (SNP) | VAF 44/241 reads (18%) | catalogued as rs1561283734; called by muse, mutect2, varscan2
- RABGAP1 | c.1446A>G p.E482= | Silent (SNP) | VAF 41/246 reads (17%) | called by muse, mutect2, varscan2
- ACADM | c.217-11T>C | Intron (SNP) | VAF 58/436 reads (13%) | called by muse, mutect2, varscan2
- ACBD5 | c.*63G>T | 3'UTR (SNP) | VAF 17/203 reads (8%) | called by muse, mutect2
- BRMS1 | c.693+114T>G | Intron (SNP) | VAF 18/248 reads (7%) | called by muse, mutect2
- DAPK2 | c.858+1854G>A | Intron (SNP) | VAF 40/320 reads (13%) | catalogued as rs925821988; called by muse, mutect2, varscan2
- DNMBP | c.2261-21109A>G | Intron (SNP) | VAF 29/158 reads (18%) | called by muse, mutect2, varscan2
- FLCN | c.396+107C>T | Intron (SNP) | VAF 53/318 reads (17%) | catalogued as rs1174891561; called by muse, mutect2, varscan2
- GLIS3 | c.-27G>T | 5'UTR (SNP) | VAF 44/325 reads (14%) | called by muse, mutect2, varscan2
- LIMCH1 | c.935+7388A>G | Intron (SNP) | VAF 14/452 reads (3%) | called by muse, mutect2
- MST1L | n.920G>C | RNA (SNP) | VAF 19/261 reads (7%) | called by muse, mutect2
- MYBPC1 | c.104-1636del | Intron (DEL) | VAF 51/395 reads (13%) | called by mutect2, pindel, varscan2
- NBPF7 | n.491G>T | RNA (SNP) | VAF 51/460 reads (11%) | called by muse, mutect2, varscan2
- NBPF7 | n.490G>T | RNA (SNP) | VAF 51/460 reads (11%) | called by muse, mutect2, varscan2
- NPL | c.230+2960C>G | Intron (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2, varscan2
- PPDPFL | c.*750G>T | 3'UTR (SNP) | VAF 47/360 reads (13%) | called by muse, mutect2, varscan2
- SH2D3C | c.516-713A>G | Intron (SNP) | VAF 16/166 reads (10%) | called by muse, mutect2
- VAPB | c.*4219A>G | 3'UTR (SNP) | VAF 52/562 reads (9%) | called by muse, mutect2
- ZNF48 | chr16:30395241 A>G | 5'Flank (SNP) | VAF 16/150 reads (11%) | called by muse, mutect2, varscan2
